Gene-level copy-number profile of tumor specimen TCGA-BR-8080-01A from TCGA case TCGA-BR-8080, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.7 years (26,546 days).
Specimen TCGA-BR-8080-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.9a910f77-4097-4e97-b401-1538d0d86fc8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8080-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8f2abae4-122e-49d6-8773-64bde8d2d804

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,929; copy number 2: 42,877; copy number 3: 3,904; copy number 4: 1,902; copy number 5: 76; copy number 6: 11; copy number 7: 39; copy number 8: 54; copy number 11: 8; copy number 23: 10; copy number 36: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8080-01A-11D-2338-01): tumor purity 0.22, ploidy 2.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 205 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:181,887,851–182,131,398, 5 genes, copy number 6 (within-gene range 1–6): AC009962.1, ITPRID2, PPP1R1C, KRT18P29, RNA5SP113.
- chr10:120,597,949–122,345,793, 27 genes, copy number 6–36: LINC01561, AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P.
- chr10:123,323,422–125,166,937, 35 genes, copy number 7–11: AL160290.2, LINC02641, AL160290.1, AL357127.2, AL357127.1, GPR26, CPXM2, AC009987.1, AC068058.1, BX469938.1, YBX2P1, AL683842.1, CHST15, OAT, NKX1-2, AL445237.1, LHPP, RPS10P18, AC068896.1, FAM53B, AL513190.1, FAM53B-AS1, EEF1AKMT2, Y_RNA, ABRAXAS2, Y_RNA, NPM1P31, AL731577.2, ZRANB1, AL731577.1, CTBP2, AL731571.1, MIR4296, AL157888.1, MRPS21P6.
- chr11:31,509,755–36,289,449, 98 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr11:76,860,867–78,079,865, 32 genes, copy number 5: ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2.
- chr13:84,867,514–85,837,532, 8 genes, copy number 7: AL445588.1, AL356313.1, LINC00375, AL160154.1, LINC00351, AL356413.1, SLITRK6, AL162373.1.

Autosomal genes at a single copy (total copy number 1): 10,087. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
